Surgical pathology report (de-identified scan), TCGA case TCGA-23-1118, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1118-01A (Primary Tumor).

[page 1 of 4]
DIAGNOSIS:

2. UTERUS, LEFT OVARY AND FALLOPIAN TUBE (HYSTERECTOMY, LEFT SALPINGO-OOPHORECTOMY):
- Left ovarian serous papillary adenocarcinoma, high grade
- Tumor size: 15 cm, solid and cystic, replacing entire ovary
- Multiple lymphovascular tumor emboli in exocervical and endocervical wall, myometrium, fallopian tube, and paraovarian/paratubal tissue
- Ovarian tumor penetrates serosa and directly invades into adherent outer myometrium

Additional Findings:

- Proliferative endometrium
- Mild chronic cervicitis
- Focal endocervical squamous metaplasia, microglandular hyperplasia, and nabothian cysts
- Left fallopian tube with foci of intravascular papillary endothelial hyperplasia
- Serosal adhesions
1. RIGHT OVARY AND FALLOPIAN TUBE (RIGHT SALPINGO-OOPHORECTOMY):
- Right ovary with:
- Metastatic adenocarcinoma, predominantly numerous lymphovascular tumor emboli
- Benign organizing hemorrhagic functional cyst (1.9 cm)
- Benign simple cyst (5.5 cm) lined by a single layer of flattened epithelial cells
- Serosal adhesions
- Fallopian tube with multiple paratubal and mural lymphovascular tumor emboli
- Paratubal Walthard rest
- Paraovarian tissue with multiple lymphovascular tumor emboli
- 3-8. OMENTUM (RESECTION AND BIOPSY):
- Few detached, free-floating clusters of tumor cells (B-E, omentum #2-#5)
- Three small omental lymph nodes (C,D,F, omentum #3,#4, and omental biopsy) with no evidence of metastatic carcinoma (0/3)
- Focal benign epithelial inclusion (A, omentum #1)
- Adhesions, mesothelial hyperplasia, mild chronic inflammation, and focal fibrinous exudate
9. APPENDIX (APPENDECTOMY):
- Multiple serosal and focal mural lymphovascular tumor emboli
- Serosal fibrinous exudate containing focal clusters of tumor cells

[page 2 of 4]
-Appendiceal tip with mucosal acute inflammation and associated granulation tissue, fibroblastic proliferation, and reactive epithelial changes consistent with early/subacute appendicitis

10. LEFT PELVIC LYMPH NODES (EXCISION):

-Four out of five lymph nodes positive for metastatic adenocarcinoma (4/5)
-Perinodal lymphovascular invasion

11. RIGHT OBTURATOR LYMPH NODES (EXCISION):

-Ten out of eleven lymph nodes positive for metastatic adenocarcinoma (10/11)
-Perinodal lymphovascular invasion

=====

HISTORY: Ovarian tumor

MICROSCOPIC:

See Diagnosis.

GROSS:

1. RIGHT OVARIAN MASS

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in the fresh state in the Operating Room for intraoperative gross and frozen consultations and subsequently fixed in formalin is an 8 x 4 x 4 cm, 70 gram grossly recognizable ovary. There is an attached 8 cm long and 1.5 cm in diameter of fallopian tube with fimbriated distal end. The ovary is significantly enlarged with a 5.5 x 4 x 3.5 cm cyst which is lined by smooth inner surface. Hemorrhagic fibrous adhesions are present on the serosal surface of ovarian tissue. The frozen section remainder measures 2.8 x 1.7 x 0.3 cm.

Representative sections.

P: Frozen section remainder - 1

Q: Proximal, middle, and distal right fallopian tube - 3

R,S: Right ovary - 1 each

T,U: Right ovarian cystic wall - 3 each

V,W: Right ovarian cyst and adjacent tissue - 1 each

2. UTERUS AND LEFT OVARY

Labeled with the patient's name, labeled as designated on the specimen requisition form, received fresh in the Operating Room for frozen section diagnosis and subsequently fixed in formalin, is a uterus with attached left ovary which weighs 1150 grams. The uterine corpus is symmetric, measuring 10 cm superior to inferior, 8 cm cornu to cornu, and 5 cm anterior to posterior. The serosa is pink with adhesions on the left cornu and the posterior uterine wall densely adherent to the left ovarian tumor. The cervix has a length of 4 cm and a diameter of 3.5 cm. There is a 1 cm slit-like patent os. The endocervical canal is 5 cm in length and is tan and rugose. The endometrial cavity is 5 cm in length, 2 cm in width, and is lined by a soft tan-red, hyperemic endometrium with a thickness of 0.2 cm. The endometrium is grossly unremarkable. The myometrium is 2.5 cm in maximum thickness. The myometrium is otherwise grossly unremarkable. The left ovary measures 14 x 13 x 15 cm and grossly replaced by tumor tissue. The serosal surface is tan-red with hemorrhagic and fibrous adhesions. Solid bulging areas and cystic areas are present. The left fallopian tube is stretched, difficult to identify and adherent to the ovarian tumor. Serial sections through the left ovary show solid and cystic tumor tissue replacing the ovarian tissue. Cut surface of the tumor tissue is tan solid with nodular and papillary appearance. Necrosis is present with no evidence of hemorrhage. Multiple cysts are present ranging from 3 to 6 cm in greatest dimensions. Foci of papillary cystic lining are present. Frozen section remainder measures 2.2 x 1.5 x 0.3 cm in greatest dimensions. Representative sections.

[page 3 of 4]
X: Frozen section remnant - 1
Y: Anterior cervix - 1
Z: Anterior uterine wall - 1
AA: Posterior cervix - 1
BB: Posterior uterine wall - 1
CC,DD: Solid portion of left ovarian tumor - 1 each
EE,FF: Cystic wall with papillary projection - 1 each
GG: Smooth cystic wall - 3
HH-JJ: Tumor and the serosal surface - 1 each
ADDITIONAL SECTIONS:
KK,LL: Possible left fallopian tube - 2 each
MM: Left ovarian tumor and fundus - 1
NN,OO: Left ovarian tumor and posterior uterine wall - 1 each

3. OMENTUM NUMBER 1

Labeled with the patient's name, labeled as designated on the specimen requisition form and received in formalin, is a soft tan-red piece of omentum tissue measuring 5.5 x 2.5 x 0.6 cm in greatest dimensions. Representative sections.

A. 2

4. OMENTUM NUMBER 2

Labeled with the patient's name, labeled as designated on the specimen requisition form and received in formalin, is a soft tan-red piece of omentum tissue measuring 9 x 5 x 0.6 cm in greatest dimensions. Representative sections.

B. 4

5. OMENTUM NUMBER 3

Labeled with the patient's name, labeled as designated on the specimen requisition form and received in formalin, is a soft tan-red piece of omentum tissue measuring 8 x 7 x 0.6 cm in greatest dimensions. Representative sections.

C. 5

6. OMENTUM NUMBER 4

Labeled with the patient's name, labeled as designated on the specimen requisition form and received in formalin, is a soft pink-tan flat piece of omentum tissue measuring 12.5 x 3 x 0.6 cm in greatest dimensions. Representative sections.

D. 4

7. OMENTUM NUMBER 5

Labeled with the patient's name, labeled as designated on the specimen requisition form and received in formalin, is a soft pink-tan flat piece of omentum tissue measuring 4 x 3.5 x 0.6 cm in greatest dimensions. Representative sections.

E. 4

8. OMENTAL BIOPSY

Labeled with the patient's name, labeled as designated on the specimen requisition form and received in formalin, is a soft tan 0.7 x 0.6 x 0.5 cm irregular portion of tissue. Entirely submitted.

F. 1

9. APPENDIX

Labeled with the patient's name, labeled as designated on the specimen requisition form and received in formalin, is a vermiform appendix, 6.5 cm long and 1.0 cm in maximum diameter with attached fat up to 1.0 cm in width and 0.5 cm in thickness. There are no apparent gross abnormalities. Representative sections.

G. Proximal, middle and distal appendix - 3

10. LEFT PELVIC LYMPH NODE

Labeled with the patient's name and labeled as designated on the specimen requisition form, received fresh in the Operating Room for

[page 4 of 4]
frozen section diagnosis and subsequently fixed in formalin, is a piece of fibroconnective tissue containing two enlarged lymph nodes measuring 2.5 and 4.5 cm in greatest dimensions. Grossly, both lymph nodes are replaced by tumor tissue. The frozen section remnant measures 2.0 x 2.0 x 0.3 cm in greatest dimensions. Representative sections.

H. Frozen section remnant - 1

I. Larger lymph node - 2

J. Smaller lymph nodes - 1

11. RIGHT OBTURATOR LYMPH NODES

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin, are four soft tan-red irregular pieces of soft tissue fragments ranging from 1.1 to 4.7 cm in greatest dimensions. Ten lymph nodes were dissected from adipose tissue, ranging from 0.9 to 2.5 cm in greatest dimensions. Representative sections.

K,L. Lymph nodes - 3 each

M. Lymph nodes - 2

N. One lymph node, bisected - 2

O. One lymph node, bisected - 2

OPERATIVE CONSULT (GROSS):

1: Right ovarian mass:

-Simple cyst with surrounding edematous ovarian stroma

3: Left ovary:

OPERATIVE CONSULT (FROZEN):

1: Right ovarian mass:

-Carcinoma, predominantly within vascular spaces

2: Left ovary:

-Poorly differentiated carcinoma

10: Left pelvic lymph node:

-Metastatic carcinoma, poorly differentiated

Source: NCI Genomic Data Commons file e8590779-1e00-4848-8b26-941f7ead0b5b (TCGA-23-1118.2F53A2C6-B67A-4966-B300-5E00968B15F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).